Gene-level copy-number profile of tumor specimen C3N-02190-01 (profiled together with C3N-02190-02) from CPTAC case C3N-02190, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 53.5 years (19,534 days).
Specimen C3N-02190-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Occipital Cortex; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 22df52ea-8962-46e2-8be4-df1df186eae7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02190-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,706 have no estimate.
https://portal.gdc.cancer.gov/files/10a24c5d-0dd4-4d0a-af4b-53dada7061bd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 41; copy number 1: 9,720; copy number 2: 46,065; copy number 3: 3,068; copy number 4: 23.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,455,740, 16 genes (within-gene range 0–1): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.
- chr17:30,906,344–31,095,450, 14 genes (within-gene range 0–1): ADAP2, AC138207.1, RN7SL138P, AC138207.5, AC138207.9, RNF135, AC138207.4, DPRXP4, AC138207.7, AC138207.3, AC138207.8, AC138207.6, AC138207.2, MIR4733.
- chr17:31,133,182–31,138,518, 1 gene (within-gene range 0–1): AC079915.1.
- chr22:18,855,621–18,894,407, 3 genes (within-gene range 0–1): BCRP7, FAM230F, AC008103.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 6,872. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
